Somatic mutation profile of cancer-model specimen HCM-BROD-0106-C71-85A (3D Neurosphere, passage 3; aliquot HCM-BROD-0106-C71-85A-01D-A79L-36), derived from the recurrence tumor of HCMI case HCM-BROD-0106-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.7 years (19,261 days).
Specimen HCM-BROD-0106-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a10a1c40-6a6b-427e-af61-3bbdaf047cd3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0106-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0106-C71-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c6a6c27-eabe-4d64-b372-8d7e97f4e0a5

The open-access MAF lists 2,333 somatic variants for this specimen: 1,497 protein-altering or splice-affecting, 739 silent, 97 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,354, Silent 739, Nonsense Mutation 67, Intron 49, Splice Region 33, Splice Site 29, 3'UTR 19, 5'UTR 12, 5'Flank 10, Frame Shift Del 8, 3'Flank 5, Translation Start Site 3.

Variants (750 of 2,333; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LMNA | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 177/1214 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1228406418, CD156162, CM123360, COSV61544159; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 100/448 reads (22%) | catalogued as rs1554306528, COSV56151812; ClinVar: pathogenic; called by muse, mutect2
- PTEN | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 52/150 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs398123322, COSV64289089, COSV64294277; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 13/199 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2
- AAAS | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 71/297 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV52932614; called by muse, mutect2, varscan2
- AAMDC | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs749128498; called by muse, mutect2, varscan2
- AATK | c.1616C>T p.P539L (on ENST00000326724 / NM_001080395.3; = p.P436L on NM_004920.2) | Missense Mutation (SNP) | VAF 217/816 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs1159505516; called by muse, mutect2, varscan2
- ABCB9 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 44/618 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs757932330; called by muse, mutect2
- ABCD2 | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 41/323 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.28); catalogued as rs1288059904; called by muse, mutect2, varscan2
- ABCG4 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 68/261 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1173227072; called by muse, mutect2, varscan2
- ABHD18 | c.821C>T p.S274F (on ENST00000398965 / NM_001039717.2; = p.S181F on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/319 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs1163813206; called by muse, mutect2
- ACD | c.395C>T p.S132F (on ENST00000620338; = p.S43F on NM_022914.3) | Missense Mutation (SNP) | VAF 120/625 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs1364303645; called by muse, mutect2, varscan2
- ACE2 | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53026021; called by muse, mutect2
- ACKR2 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 28/499 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.944); catalogued as COSV56178145; called by muse, mutect2
- ACKR4 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV51443059; called by muse, mutect2, varscan2
- ACOT1 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 65/337 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs780868134; called by muse, mutect2, varscan2
- ACTN3 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 30/837 reads (4%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1325834987; called by muse, mutect2
- ADA | c.715G>A p.G239S | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777820729, CM034199; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM7 | c.2003-1G>A p.X668_splice | Splice Site (SNP) | VAF 51/225 reads (23%) | catalogued as COSV99443659; called by muse, mutect2, varscan2
- ADAMTS14 | c.3173C>T p.S1058L | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV104427851, COSV64601106; called by muse, mutect2, varscan2
- ADAMTS20 | c.5559G>T p.L1853F | Missense Mutation (SNP) | VAF 103/230 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs752671454; called by muse, mutect2, varscan2
- ADGRD2 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 36/1070 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs1255287790; called by muse, mutect2
- AFF4 | c.1050G>A p.K350= | Splice Region (SNP) | VAF 41/156 reads (26%) | catalogued as rs941856604; called by muse, mutect2, varscan2
- AFM | c.747G>T p.K249N | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV56919038; called by muse, mutect2, varscan2
- AHNAK | c.11467G>A p.D3823N | Missense Mutation (SNP) | VAF 57/470 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.302); catalogued as rs371787684, COSV57226790; called by muse, mutect2, varscan2
- AKAP8 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 96/567 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs1384334246; called by muse, mutect2, varscan2
- AL136295.3 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 116/203 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as rs1303346283; called by muse, mutect2, varscan2
- ALCAM | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.926); catalogued as COSV60255127; called by muse, mutect2
- ALOX12B | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 25/259 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.035); catalogued as rs1373757925; called by muse, mutect2
- ANGEL2 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as COSV100853899; called by muse, mutect2
- ANKRD17 | c.3394G>A p.V1132M | Missense Mutation (SNP) | VAF 139/307 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1259589863; called by muse, mutect2, varscan2
- ANKRD24 | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 234/747 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.094); catalogued as rs769988640; called by muse, mutect2, varscan2
- ANKRD36 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); catalogued as rs537628459; called by muse, mutect2, varscan2
- ANKRD39 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 163/540 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1446519969; called by muse, mutect2, varscan2
- ANKRD60 | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1407596886; called by muse, mutect2
- AP3D1 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 101/655 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.678); catalogued as rs1447066782; called by muse, varscan2
- AP3D1 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 53/506 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs374552258; called by muse, varscan2
- APCDD1L | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 38/881 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.173); catalogued as rs1265867277; called by muse, mutect2
- ARFGAP1 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 34/402 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs1430730554; called by muse, mutect2
- ARID4A | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV104415653; called by muse, mutect2, varscan2
- ARID5B | c.3368C>T p.S1123L | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as COSV99689192; called by muse, mutect2
- ARX | c.986G>A p.R329K | Missense Mutation (SNP) | VAF 21/442 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as COSV66875604; called by muse, mutect2
- ASIC3 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 20/679 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs1414278953; called by muse, mutect2
- ATAD2B | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.615); catalogued as COSV53206448; called by muse, mutect2, varscan2
- ATP10D | c.516G>A p.W172* | Nonsense Mutation (SNP) | VAF 86/300 reads (29%) | catalogued as COSV56714161; called by muse, mutect2, varscan2
- ATP13A2 | c.2726G>A p.S909N | Missense Mutation (SNP) | VAF 161/484 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1377555231; called by muse, mutect2, varscan2
- ATP2B1 | c.1301G>A p.G434D | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53803798; called by muse, mutect2, varscan2
- BAZ2B | c.5186C>T p.A1729V | Missense Mutation (SNP) | VAF 116/269 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs1351460568, COSV100601013; called by muse, mutect2, varscan2
- BCAT1 | c.674+1G>A p.X225_splice | Splice Site (SNP) | VAF 33/176 reads (19%) | catalogued as rs1055108947, COSV99678188; called by muse, varscan2
- BDP1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 27/739 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV62431921; called by muse, mutect2
- BEGAIN | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 31/824 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.616); catalogued as COSV62067999; called by muse, mutect2
- BRD7 | c.1859C>T p.P620L | Missense Mutation (SNP) | VAF 19/369 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54265323; called by muse, mutect2
- BRD8 | c.2500G>A p.D834N (on ENST00000254900 / NM_139199.2; = p.D907N on NM_006696.4) | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV50145602; called by muse, mutect2, varscan2
- BRINP3 | c.2062G>A p.D688N | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.977); catalogued as COSV99054923; called by muse, mutect2
- BRIP1 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 19/301 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs1567878087; ClinVar: uncertain significance; called by muse, mutect2
- BTBD7 | c.2386C>T p.P796S | Missense Mutation (SNP) | VAF 165/522 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs745781357, COSV58290104; called by muse, mutect2, varscan2
- BTN2A1 | c.84C>T p.A28= | Splice Region (SNP) | VAF 30/189 reads (16%) | catalogued as rs1054191841; called by muse, mutect2, varscan2
- C12orf56 | c.1801C>T p.P601S (on ENST00000543942 / NM_001170633.2; = p.P441S on NM_001099676.3) | Missense Mutation (SNP) | VAF 51/284 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100398916; called by muse, mutect2, varscan2
- C3orf33 | c.484G>A p.G162S (on ENST00000340171 / NM_001308229.2; = p.G119S on NM_173657.2) | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); catalogued as rs1189444289; called by muse, mutect2, varscan2
- C7orf33 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 194/417 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs1224082344; called by muse, mutect2, varscan2
- C9orf72 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs753335393; called by muse, mutect2, varscan2
- CACNA1A | c.761C>T p.T254I | Missense Mutation (SNP) | VAF 76/354 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.663); catalogued as COSV64191881; called by muse, mutect2, varscan2
- CACNA1C | c.2935G>A p.V979M | Missense Mutation (SNP) | VAF 22/293 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1555874590; ClinVar: uncertain significance; called by muse, mutect2
- CACNA2D1 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 68/307 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV62386961; called by muse, mutect2, varscan2
- CAMSAP2 | c.2911C>G p.P971A (on ENST00000236925 / NM_001297707.2; = p.P960A on NM_203459.3) | Missense Mutation (SNP) | VAF 124/411 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.937); catalogued as COSV52671262; called by muse, mutect2, varscan2
- CAMTA1 | c.1406C>T p.T469I | Missense Mutation (SNP) | VAF 28/570 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV57923369; called by muse, mutect2
- CASQ1 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 31/714 reads (4%) | SIFT tolerated (0.97); PolyPhen benign (0.028); catalogued as rs1413526795; called by muse, mutect2
- CATSPERD | c.1398G>A p.W466* | Nonsense Mutation (SNP) | VAF 86/527 reads (16%) | catalogued as rs1484343340; called by muse, mutect2, varscan2
- CBFA2T3 | c.137G>A p.R46K | Missense Mutation (SNP) | VAF 108/413 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.027); catalogued as COSV99241559; called by muse, mutect2, varscan2
- CBLL1 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 156/339 reads (46%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1322995812, COSV99755686; called by muse, mutect2, varscan2
- CCDC142 | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 64/586 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as rs749980258; called by muse, mutect2, varscan2
- CCDC182 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 52/644 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.981); catalogued as rs1404487975; called by muse, mutect2
- CCDC85C | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 136/577 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs551305610; called by muse, mutect2, varscan2
- CD27 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 26/403 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.511); catalogued as COSV56948764; called by muse, mutect2
- CD300LD | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 94/287 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV60083626; called by muse, mutect2, varscan2
- CD33 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 38/734 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV51805055; called by muse, mutect2
- CD96 | c.1612C>T p.L538F (on ENST00000283285 / NM_198196.3; = p.L522F on NM_005816.5) | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV51916140, COSV99343628; called by muse, mutect2
- CDC20 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 141/502 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs1484301576; called by muse, mutect2, varscan2
- CDK10 | c.44G>A p.C15Y | Missense Mutation (SNP) | VAF 166/553 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs748993161; called by muse, mutect2, varscan2
- CDKL4 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 137/302 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs370476409, COSV101115440; called by muse, mutect2, varscan2
- CDKN2AIP | c.1025C>T p.T342I | Missense Mutation (SNP) | VAF 39/423 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs372360098; called by muse, mutect2
- CENPC | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 59/270 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as COSV56626043; called by muse, mutect2, varscan2
- CEP41 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 138/438 reads (32%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs782809600, COSV56221025; called by muse, mutect2, varscan2
- CETN3 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 64/227 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375438485; called by muse, mutect2, varscan2
- CHI3L1 | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 151/496 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1171734053; called by muse, mutect2, varscan2
- CHID1 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs767711694; called by muse, mutect2
- CHP2 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 40/484 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs752168503; called by muse, mutect2
- CHRNA1 | c.1293G>A p.M431I (on ENST00000261007 / NM_001039523.3; = p.M406I on NM_000079.4) | Missense Mutation (SNP) | VAF 56/261 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.142); catalogued as COSV53684411; called by muse, mutect2, varscan2
- CHST5 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 54/730 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs955459603, COSV60341677; called by muse, mutect2
- CHUK | c.689+1G>A p.X230_splice | Splice Site (SNP) | VAF 40/84 reads (48%) | catalogued as COSV64917987; called by muse, mutect2, varscan2
- CIC | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 160/629 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.043); catalogued as rs1269587855; called by muse, mutect2, varscan2
- CLCC1 | c.1093G>A p.G365S (on ENST00000356970 / NM_001377464.1; = p.G315S on NM_015127.5) | Missense Mutation (SNP) | VAF 48/425 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.269); catalogued as rs767914869, COSV56763601; called by muse, mutect2, varscan2
- CLEC16A | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs1478251636; called by muse, mutect2
- CNOT10 | c.2134G>A p.V712M | Missense Mutation (SNP) | VAF 99/423 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.293); catalogued as rs150502445; called by muse, mutect2, varscan2
- COL12A1 | c.175G>A p.V59M | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV59397776; called by muse, mutect2, varscan2
- COL3A1 | c.2765C>T p.P922L | Missense Mutation (SNP) | VAF 135/442 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100483544; called by muse, mutect2, varscan2
- COL5A1 | c.2447C>T p.P816L | Missense Mutation (SNP) | VAF 44/486 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1418579599; called by muse, mutect2
- CPT1C | c.2324C>T p.S775L | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs772906026; called by muse, mutect2, varscan2
- CRACR2B | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 137/481 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs1464679913; called by muse, mutect2, varscan2
- CREBBP | c.6464C>T p.P2155L | Missense Mutation (SNP) | VAF 114/441 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.108); catalogued as rs1470176774; called by muse, mutect2, varscan2
- CSF2RB | c.977G>A p.R326K | Missense Mutation (SNP) | VAF 118/436 reads (27%) | SIFT tolerated (0.91); PolyPhen benign (0.012); catalogued as rs752076635; called by muse, varscan2
- CSF2RB | c.2489C>T p.P830L | Missense Mutation (SNP) | VAF 91/544 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs1431256083, COSV53256887; called by muse, mutect2, varscan2
- CTNND2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 43/270 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV58869680; called by muse, mutect2, varscan2
- CUX2 | c.2054C>T p.P685L | Missense Mutation (SNP) | VAF 24/764 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1368637940; called by muse, mutect2
- CXorf66 | c.880A>T p.T294S | Missense Mutation (SNP) | VAF 125/126 reads (99%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV65169631; called by muse, mutect2, varscan2
- CYP3A4 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 68/312 reads (22%) | catalogued as COSV60501795; called by muse, mutect2, varscan2
- CYP4F12 | c.1314G>A p.E438= | Splice Region (SNP) | VAF 76/436 reads (17%) | catalogued as COSV61176454; called by muse, varscan2
- DAG1 | c.1802G>A p.G601E | Missense Mutation (SNP) | VAF 173/512 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as rs781242650; called by muse, mutect2, varscan2
- DENND1B | c.1714C>T p.L572F | Missense Mutation (SNP) | VAF 100/346 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0.389); catalogued as COSV54143211; called by muse, mutect2
- DES | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 121/243 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV64660663; called by muse, mutect2, varscan2
- DEUP1 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 81/242 reads (33%) | catalogued as rs566601356, COSV53210337; called by muse, mutect2, varscan2
- DGAT1 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as rs782804473; called by muse, mutect2
- DHX29 | c.3907G>A p.E1303K | Missense Mutation (SNP) | VAF 67/282 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV52419268; called by muse, mutect2, varscan2
- DIP2A | c.4498G>A p.V1500M | Missense Mutation (SNP) | VAF 115/394 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1421598695; called by muse, mutect2, varscan2
- DISP2 | c.2356C>T p.P786S | Missense Mutation (SNP) | VAF 268/538 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.647); catalogued as rs559564519; called by muse, mutect2, varscan2
- DLD | c.1186C>T p.H396Y | Missense Mutation (SNP) | VAF 38/341 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.993); catalogued as rs1331406985; called by muse, mutect2, varscan2
- DMRT3 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 96/193 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1160656522; called by muse, mutect2, varscan2
- DNHD1 | c.9810G>A p.W3270* | Nonsense Mutation (SNP) | VAF 87/309 reads (28%) | catalogued as rs1314837820; called by muse, mutect2, varscan2
- DOK3 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 21/394 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.118); catalogued as rs959633389; called by muse, mutect2
- DPEP1 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 24/455 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV55360633; called by muse, mutect2
- DPEP2 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 85/172 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs755590475, COSV52055998; called by muse, varscan2
- DPP10 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 65/221 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59722322; called by muse, mutect2, varscan2
- DSCAM | c.2143G>A p.G715S | Missense Mutation (SNP) | VAF 61/288 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV68021616; called by muse, mutect2, varscan2
- DTX2 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 167/948 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs745386317; called by muse, varscan2
- DUOXA2 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 198/441 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs773820761; called by muse, mutect2, varscan2
- DUSP1 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 158/561 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1263882417; called by muse, mutect2, varscan2
- E2F4 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 32/322 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV100681966; called by muse, varscan2
- ECE1 | c.2225C>T p.S742F | Missense Mutation (SNP) | VAF 92/504 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51670782; called by muse, mutect2, varscan2
- EDRF1 | c.2836G>A p.A946T (on ENST00000356792 / NM_001202438.2; = p.A912T on NM_015608.2) | Missense Mutation (SNP) | VAF 74/125 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61763401; called by muse, mutect2, varscan2
- EFR3A | c.1206G>A p.M402I | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV54459349; called by muse, mutect2, varscan2
- EGF | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as rs776647507, COSV54479485; called by muse, mutect2, varscan2
- EIF2AK1 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 50/722 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99551936; called by muse, mutect2
- EIF4G1 | c.2297C>T p.S766F (on ENST00000346169 / NM_198241.3; = p.S571F on NM_004953.5) | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV100072424; called by muse, mutect2, varscan2
- EMC1 | c.2950C>T p.Q984* | Nonsense Mutation (SNP) | VAF 52/196 reads (27%) | catalogued as rs1427612524; called by muse, mutect2, varscan2
- ENHO | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 42/406 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.052); catalogued as COSV54285194; called by muse, mutect2
- EPHA5 | c.2765G>A p.R922K | Missense Mutation (SNP) | VAF 120/397 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56677447; called by muse, mutect2, varscan2
- EPHA7 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1562059593; called by muse, mutect2, varscan2
- EPHB3 | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 152/589 reads (26%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.892); catalogued as rs1260263685; called by muse, mutect2, varscan2
- EPM2A | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs796052429; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPN1 | c.1067-1G>A p.X356_splice (on ENST00000270460 / NM_001321263.1; = p.X331_splice on NM_013333.3) | Splice Site (SNP) | VAF 110/564 reads (20%) | catalogued as COSV50035880; called by muse, mutect2, varscan2
- EPN1 | c.1313C>T p.A438V (on ENST00000270460 / NM_001321263.1; = p.A412V on NM_013333.3) | Missense Mutation (SNP) | VAF 73/1213 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.232); catalogued as rs374472448; called by muse, mutect2
- ERBB4 | c.2551G>A p.V851M | Missense Mutation (SNP) | VAF 32/434 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs537545486; called by muse, mutect2
- ERC2 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 15/378 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV55648977, COSV99891774; called by muse, mutect2
- EYA1 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 63/288 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD082096; called by muse, mutect2, varscan2
- F9 | c.1294G>A p.G432S | Missense Mutation (SNP) | VAF 122/229 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1170838100, CM940724; called by muse, mutect2, varscan2
- FAM199X | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 105/201 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV55434495; called by muse, mutect2, varscan2
- FAM221B | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 65/249 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as rs753385887; called by muse, mutect2, varscan2
- FARP2 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 85/345 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs754939717, COSV99884476; called by muse, mutect2, varscan2
- FAT1 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 17/442 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV71675245; called by muse, mutect2
- FAT2 | c.5327T>A p.M1776K | Missense Mutation (SNP) | VAF 155/314 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV55818404; called by muse, mutect2, varscan2
- FAT2 | c.3227G>A p.G1076E | Missense Mutation (SNP) | VAF 53/208 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV55819716; called by muse, mutect2, varscan2
- FAT3 | c.7963C>T p.P2655S | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.984); catalogued as COSV53092684; called by muse, mutect2
- FAT3 | c.9790G>A p.D3264N | Missense Mutation (SNP) | VAF 50/308 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV104401802; called by muse, mutect2, varscan2
- FBN2 | c.7112C>T p.S2371L | Missense Mutation (SNP) | VAF 94/180 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1461140915, COSV52509999; called by muse, mutect2, varscan2
- FBN3 | c.4876G>A p.G1626R | Missense Mutation (SNP) | VAF 44/370 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207987065; called by muse, mutect2, varscan2
- FBXL6 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 149/535 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.039); catalogued as rs781903714; called by muse, mutect2, varscan2
- FCHSD1 | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 153/549 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs1258591049; called by muse, mutect2, varscan2
- FERMT3 | c.1828G>A p.A610T (on ENST00000279227 / NM_178443.3; = p.A606T on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/246 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.223); catalogued as rs1438403859; called by muse, mutect2, varscan2
- FILIP1 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 84/425 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV99384167, COSV99385219; called by muse, mutect2, varscan2
- FLG | c.1960A>G p.R654G | Missense Mutation (SNP) | VAF 432/432 reads (100%) | SIFT tolerated (1); PolyPhen possibly damaging (0.879); catalogued as rs758025810, COSV64243164; called by muse, mutect2, varscan2
- FLT4 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 59/470 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56099015; called by muse, mutect2, varscan2
- FMN2 | c.3344G>A p.G1115E | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs1248062589, COSV100147120; called by muse, varscan2
- FSTL1 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200742219; called by muse, mutect2, varscan2
- GALNTL6 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72491251; called by muse, mutect2, varscan2
- GALT | c.1105G>A p.G369R | Missense Mutation (SNP) | VAF 83/310 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs751740223, COSV58840554; called by muse, mutect2, varscan2
- GAS2L1 | c.1730G>A p.C577Y | Missense Mutation (SNP) | VAF 141/563 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs754821032; called by muse, mutect2, varscan2
- GDF5 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 189/636 reads (30%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs749564274; called by muse, mutect2, varscan2
- GDPD4 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV60016782; called by muse, mutect2, varscan2
- GET3 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 90/568 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as rs755532882; called by muse, mutect2, varscan2
- GLRX2 | c.124G>A p.E42K (on ENST00000367439 / NM_197962.3; = p.E43K on NM_016066.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/340 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.026); catalogued as COSV100814133, COSV100814215; called by muse, mutect2
- GORAB | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 17/323 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100883755; called by muse, mutect2
- GPAA1 | c.1222G>A p.G408S | Missense Mutation (SNP) | VAF 51/458 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as rs782630422; called by muse, mutect2, varscan2
- GPR108 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 65/536 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs1332376893; called by muse, mutect2, varscan2
- GPR146 | c.628C>T p.L210F | Missense Mutation (SNP) | VAF 42/744 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs1423918441; called by muse, mutect2
- GPR18 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.033); catalogued as COSV61621208; called by muse, mutect2
- GRIN3A | c.3145C>T p.P1049S | Missense Mutation (SNP) | VAF 15/400 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.554); catalogued as rs1329185625, COSV104422457; called by muse, mutect2
- GRIP2 | c.368G>A p.G123E (on ENST00000619221; = p.G26E on NM_001080423.4) | Missense Mutation (SNP) | VAF 148/388 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.568); catalogued as rs1275531099; called by muse, mutect2, varscan2
- GSTCD | c.1867C>T p.P623S (on ENST00000360505 / NM_001031720.3; = p.P536S on NM_024751.3) | Missense Mutation (SNP) | VAF 80/299 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64736203; called by muse, mutect2, varscan2
- GUSB | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 55/427 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100512627; called by muse, mutect2, varscan2
- H2AC4 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 88/292 reads (30%) | catalogued as rs764354439; called by muse, mutect2, varscan2
- HAO2 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV58039600; called by muse, mutect2
- HDGF | c.60G>A p.M20I | Missense Mutation (SNP) | VAF 143/817 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as COSV61975643; called by muse, mutect2, varscan2
- HECW1 | c.3307C>T p.R1103* | Nonsense Mutation (SNP) | VAF 54/428 reads (13%) | catalogued as COSV101223143; called by muse, mutect2, varscan2
- HHAT | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.683); catalogued as rs773212620; called by muse, mutect2
- HIVEP3 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 239/505 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs750482011, COSV56024196; called by muse, mutect2, varscan2
- HM13 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59438472; called by muse, mutect2
- HMCN1 | c.14440G>A p.D4814N | Missense Mutation (SNP) | VAF 74/228 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs771468869, COSV54886402; called by muse, mutect2, varscan2
- HMCN1 | c.16542G>A p.G5514= | Splice Region (SNP) | VAF 38/200 reads (19%) | catalogued as rs1410341592; called by muse, mutect2, varscan2
- HOXD8 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 145/603 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as rs780060302, COSV57485960; called by muse, mutect2, varscan2
- HS3ST3A1 | c.597C>T p.Y199= | Splice Region (SNP) | VAF 111/205 reads (54%) | catalogued as rs1024554136; called by muse, mutect2, varscan2
- HTR3E | c.788C>T p.A263V (on ENST00000415389 / NM_001256613.1; = p.A278V on NM_182589.2) | Missense Mutation (SNP) | VAF 19/410 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.917); catalogued as COSV100093706; called by muse, mutect2
- HYOU1 | c.1510G>A p.G504R | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.582); catalogued as COSV68215647; called by muse, mutect2, varscan2
- ICE1 | c.2030C>T p.T677I | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1362108054; called by muse, mutect2, varscan2
- IDE | c.1720C>T p.L574F | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs1390374448; called by muse, mutect2, varscan2
- IFT46 | c.589A>G p.T197A (on ENST00000264021 / NM_001168618.2; = p.T248A on NM_020153.3) | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.757); catalogued as rs961570694; called by muse, mutect2, varscan2
- IGFBP1 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 153/996 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1229002119; called by muse, mutect2, varscan2
- IGHV2-26 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 94/362 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1192034416; called by muse, mutect2, varscan2
- IGHV2-70 | c.47G>A p.W16* | Nonsense Mutation (SNP) | VAF 26/130 reads (20%) | catalogued as rs537379391; called by muse, mutect2, varscan2
- IGHV3-66 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.036); catalogued as rs377538322; called by muse, mutect2, varscan2
- IGSF1 | c.3488C>T p.P1163L | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100811995; called by muse, mutect2
- IGSF9 | c.1915G>A p.V639I (on ENST00000368094 / NM_001135050.2; = p.V623I on NM_020789.4) | Missense Mutation (SNP) | VAF 106/893 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV63641012; called by muse, mutect2, varscan2
- IKZF4 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 125/537 reads (23%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.043); catalogued as rs756248837; called by muse, mutect2, varscan2
- IL17RC | c.1151G>A p.S384N (on ENST00000295981 / NM_153461.4; = p.S298N on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 167/561 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.084); catalogued as rs202092337; called by muse, mutect2, varscan2
- IL1R2 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.399); catalogued as rs147924293; called by muse, mutect2, varscan2
- IL27RA | c.1325G>A p.R442K | Missense Mutation (SNP) | VAF 34/1031 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as COSV99652281; called by muse, mutect2
- ILDR1 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 112/438 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99878930; called by muse, mutect2, varscan2
- INPP5J | c.2514G>A p.Q838= (on ENST00000331075 / NM_001284285.2; = p.Q470= on NM_001002837.2) | Splice Region (SNP) | VAF 53/225 reads (24%) | catalogued as rs1197529097, COSV99311939; called by muse, mutect2, varscan2
- INPPL1 | c.1624G>A p.G542R | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778129558; called by muse, mutect2, varscan2
- INTU | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 81/293 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV99611427; called by muse, mutect2, varscan2
- INVS | c.1234G>A p.G412S | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV52449841; called by muse, mutect2, varscan2
- IQCF1 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 51/245 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs751170124; called by muse, mutect2, varscan2
- IRAK1BP1 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 30/584 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV64048158; called by muse, mutect2
- IRF2BP1 | c.964C>T p.H322Y | Missense Mutation (SNP) | VAF 71/703 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs1017144499; called by muse, mutect2, varscan2
- IRS4 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 20/400 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV64535960; called by muse, mutect2
- JCAD | c.929G>A p.S310N | Missense Mutation (SNP) | VAF 15/312 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV64760647; called by muse, mutect2
- KALRN | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.728); catalogued as COSV53774369; called by muse, mutect2
- KAT6A | c.5174G>A p.S1725N | Missense Mutation (SNP) | VAF 85/327 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769558477; called by muse, mutect2, varscan2
- KCNC2 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 329/663 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100129849, COSV54365172; called by muse, mutect2, varscan2
- KCNJ10 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 42/968 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); catalogued as COSV100927940; called by muse, mutect2
- KCNN3 | c.905C>T p.T302I | Missense Mutation (SNP) | VAF 49/682 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as rs764058022, COSV55220320; called by muse, mutect2
- KHK | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 20/413 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV99566126; called by muse, mutect2
- KIAA1586 | c.1488G>A p.W496* | Nonsense Mutation (SNP) | VAF 78/249 reads (31%) | catalogued as rs777897727; called by muse, mutect2, varscan2
- KIAA1755 | c.3521G>A p.G1174E | Missense Mutation (SNP) | VAF 30/534 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.568); catalogued as rs1178106378; called by muse, mutect2
- KIF19 | c.2630G>A p.G877D | Missense Mutation (SNP) | VAF 34/699 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1165769990; called by muse, mutect2
- KIF26B | c.4798C>T p.P1600S | Missense Mutation (SNP) | VAF 165/822 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs765127008; called by muse, mutect2, varscan2
- KLC4 | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 50/329 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV52434952; called by muse, mutect2, varscan2
- KMT2D | c.6395C>T p.P2132L | Missense Mutation (SNP) | VAF 106/659 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.373); catalogued as rs770113503; called by muse, mutect2, varscan2
- KMT2D | c.3188G>A p.G1063E | Missense Mutation (SNP) | VAF 99/404 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs779943013; called by muse, mutect2, varscan2
- KREMEN1 | c.91+3C>T | Splice Region (SNP) | VAF 45/387 reads (12%) | catalogued as rs1217582278, COSV59913486; called by muse, mutect2, varscan2
- LARP7 | c.-2G>A | Splice Region (SNP) | VAF 43/146 reads (29%) | catalogued as rs764055993; called by muse, mutect2, varscan2
- LCA5 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63971794; called by muse, mutect2, varscan2
- LCK | c.965-1G>A p.X322_splice | Splice Site (SNP) | VAF 168/350 reads (48%) | catalogued as COSV60743020; called by muse, mutect2, varscan2
- LGALS3BP | c.1470G>A p.W490* | Nonsense Mutation (SNP) | VAF 31/488 reads (6%) | catalogued as rs1230962337; called by muse, mutect2
- LGR6 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 224/892 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV66156114; called by muse, mutect2, varscan2
- LILRB1 | c.149G>A p.S50N (on ENST00000427581; = p.S14N on NM_006669.6) | Missense Mutation (SNP) | VAF 100/444 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as COSV61120571; called by muse, mutect2
- LPIN1 | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs765092602; called by muse, mutect2, varscan2
- LRRC8A | c.1999C>T p.L667F | Missense Mutation (SNP) | VAF 61/691 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs371206145; called by muse, mutect2
- LRRIQ1 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 17/214 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV101277756; called by muse, mutect2
- LZTS2 | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 19/426 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.223); catalogued as COSV64652577; called by muse, mutect2
- MAB21L4 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 250/522 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs201848788; called by muse, mutect2, varscan2
- MACF1 | c.19260G>A p.W6420* (on ENST00000372915; = p.W4465* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 50/186 reads (27%) | catalogued as COSV57140796; called by muse, mutect2, varscan2
- MAGEC3 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.365); catalogued as COSV53577134; called by muse, mutect2
- MAGED2 | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 177/340 reads (52%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.918); catalogued as rs1191317538; called by muse, mutect2, varscan2
- MAP3K11 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 234/1062 reads (22%) | catalogued as rs773418840; called by muse, mutect2, varscan2
- MAP3K4 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as rs200950731; called by muse, mutect2, varscan2
- MAPK15 | c.239T>C p.I80T | Missense Mutation (SNP) | VAF 24/682 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1554618804; called by muse, mutect2
- MARK1 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1178036503; called by muse, mutect2, varscan2
- MAU2 | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 32/613 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV53233552; called by muse, mutect2
- MAVS | c.806G>A p.G269D | Missense Mutation (SNP) | VAF 139/459 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV63927681; called by muse, mutect2, varscan2
- MCMBP | c.1063C>T p.L355F | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.413); catalogued as rs766236785; called by muse, mutect2, varscan2
- MED26 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 31/992 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.154); catalogued as rs1369655644; called by muse, mutect2
- MEGF10 | c.2021C>T p.T674I | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as rs139700339; called by muse, mutect2, varscan2
- MFSD2A | c.737C>T p.T246I (on ENST00000372809 / NM_001136493.3; = p.T233I on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/262 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs147454339; called by muse, mutect2, varscan2
- MINDY3 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 80/137 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760037047; called by muse, mutect2, varscan2
- MIS18BP1 | c.3143C>T p.S1048F | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV60369189; called by muse, mutect2
- MMUT | c.1945C>T p.P649S | Missense Mutation (SNP) | VAF 70/242 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.905); catalogued as rs1561952053; called by muse, mutect2, varscan2
- MOG | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 119/418 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs752974529; called by muse, mutect2, varscan2
- MRE11 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60576431; called by muse, mutect2, varscan2
- MRTFB | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 87/318 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.417); catalogued as COSV57956952; called by muse, mutect2, varscan2
- MSH6 | c.3931G>A p.E1311K | Missense Mutation (SNP) | VAF 75/239 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.173); catalogued as rs749522534; called by muse, mutect2, varscan2
- MTCH2 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 19/281 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV56769482; called by muse, mutect2
- MTHFD2L | c.370C>T p.Q124* (on ENST00000395759 / NM_001144978.2; = p.Q66* on NM_001004346.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 78/286 reads (27%) | catalogued as rs371753177; called by muse, mutect2, varscan2
- MUC13 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs752491283; called by muse, mutect2, varscan2
- MUC16 | c.29135G>A p.S9712N | Missense Mutation (SNP) | VAF 57/442 reads (13%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs770208866; called by muse, mutect2, varscan2
- MUC16 | c.27917del p.S9306Tfs*103 | Frame Shift Del (DEL) | VAF 108/578 reads (19%) | catalogued as COSV67444084; called by mutect2, pindel, varscan2
- MUC16 | c.5333C>T p.T1778I | Missense Mutation (SNP) | VAF 107/645 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs201941064; called by muse, mutect2, varscan2
- MUC17 | c.13128G>A p.W4376* | Nonsense Mutation (SNP) | VAF 23/336 reads (7%) | catalogued as rs945988821, COSV60298480; called by muse, mutect2
- MXRA5 | c.3815G>A p.S1272N | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV99478118; called by muse, mutect2
- MYBBP1A | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 130/223 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); catalogued as COSV54597511; called by muse, mutect2, varscan2
- MYBL2 | c.501G>A p.R167= | Splice Region (SNP) | VAF 14/242 reads (6%) | catalogued as COSV53834417; called by muse, mutect2
- MYH11 | c.3619G>A p.E1207K | Missense Mutation (SNP) | VAF 90/483 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as rs371831822; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH6 | c.1753G>A p.G585S | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs150415679; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MYL4 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs1567749846; called by muse, mutect2, varscan2
- MYO10 | c.2351G>A p.R784K | Missense Mutation (SNP) | VAF 17/387 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV57016668; called by muse, mutect2
- MYO1D | c.2417C>T p.A806V | Missense Mutation (SNP) | VAF 71/462 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100553431; called by muse, mutect2, varscan2
- MYO1E | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs765938827, COSV99895195; called by muse, mutect2, varscan2
- MYOM1 | c.3058G>A p.G1020S | Missense Mutation (SNP) | VAF 134/476 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.823); catalogued as COSV99867979; called by muse, mutect2, varscan2
- NAPRT | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 138/523 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1364881623, COSV52785577, COSV52789086; called by muse, mutect2, varscan2
- NAT8L | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 63/326 reads (19%) | SIFT tolerated, low confidence (0.06); catalogued as rs1441963370; called by muse, mutect2, varscan2
- NBPF15 | c.1142C>T p.S381L | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.985); catalogued as rs1158821532; called by muse, mutect2, varscan2
- NCBP2 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 44/366 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.709); catalogued as COSV58318238; called by muse, mutect2, varscan2
- NCOR2 | c.5644G>A p.G1882S | Missense Mutation (SNP) | VAF 24/558 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.146); catalogued as rs1468533121, COSV62303302; called by muse, mutect2
- NDOR1 | c.1391C>T p.P464L (on ENST00000371521 / NM_001144026.3; = p.P457L on NM_014434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/672 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100789081, COSV61287368; called by muse, mutect2
- NEDD4 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 24/327 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV59064128; called by muse, mutect2
- NEK4 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1386061171, COSV51779777; called by muse, mutect2, varscan2
- NID2 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 139/554 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs575628713; called by muse, mutect2, varscan2
- NIPAL1 | c.1223C>T p.T408I | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs771765399; called by muse, mutect2, varscan2
- NIPAL2 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 113/237 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs756663093, COSV100358661; called by muse, mutect2, varscan2
- NOL4 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as COSV99306223; called by muse, mutect2, varscan2
- NOS1 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 101/228 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV57616898; called by muse, mutect2, varscan2
- NOS1AP | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 137/674 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs908347511; called by muse, mutect2, varscan2
- NOTCH2 | c.3133G>A p.G1045S | Missense Mutation (SNP) | VAF 68/120 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV56687821; called by muse, mutect2, varscan2
- NOX1 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.299); catalogued as rs748992496, COSV54194523, COSV54195624; called by muse, mutect2, varscan2
- NPAP1 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 71/447 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.134); catalogued as COSV61505829; called by muse, mutect2, varscan2
- NTN3 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 246/882 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV53546155; called by muse, varscan2
- NUCB1 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 116/470 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV99617813; called by muse, mutect2, varscan2
- NUDT13 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 90/159 reads (57%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as COSV61968016; called by muse, mutect2, varscan2
- NUP160 | c.3212G>A p.R1071K | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV101021613; called by muse, mutect2, varscan2
- OCRL | c.1138G>A p.V380M | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.174); catalogued as rs1169921099; called by muse, mutect2
- OGFOD1 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 67/230 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs775762488; called by muse, mutect2, varscan2
- OR10A3 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 111/413 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.071); catalogued as COSV62459907; called by muse, mutect2, varscan2
- OR10C1 | c.121G>A p.A41T (on ENST00000622521; = p.A39T on NM_013941.3) | Missense Mutation (SNP) | VAF 201/656 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV65822646; called by muse, mutect2, varscan2
- OR2M3 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 22/482 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.461); catalogued as COSV99081720; called by muse, mutect2
- OR2T10 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 108/361 reads (30%) | catalogued as rs1343317918; called by muse, mutect2, varscan2
- OR3A3 | c.47C>T p.T16I | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs1376550285; called by muse, mutect2, varscan2
- OR4D2 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 72/406 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1340442627; called by muse, mutect2
- OR51B5 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs985219587; called by muse, mutect2, varscan2
- OR5AP2 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 85/195 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs564090082, COSV57257559; called by muse, mutect2, varscan2
- OTOGL | c.1528G>A p.V510M (on ENST00000547103; = p.V501M on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 141/317 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.399); catalogued as rs747153629; called by muse, mutect2, varscan2
- OXTR | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 31/407 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774370884; called by muse, mutect2
- PALM3 | c.820G>A p.V274M (on ENST00000340790; = p.V289M on NM_001145028.2) | Missense Mutation (SNP) | VAF 225/907 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.561); catalogued as rs576725512; called by muse, mutect2, varscan2
- PAPLN | c.782G>A p.G261E (on ENST00000554301; = p.G234E on NM_173462.4) | Missense Mutation (SNP) | VAF 62/725 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1433536565; called by muse, mutect2
- PAXBP1 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 30/978 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs928257947; called by muse, mutect2
- PCDH10 | c.3022G>A p.A1008T | Missense Mutation (SNP) | VAF 104/343 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs759439564, COSV52091752; called by muse, mutect2, varscan2
- PCDHA3 | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 141/469 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); catalogued as COSV63539111; called by muse, mutect2, varscan2
- PCDHGA4 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 92/332 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs779796121, COSV53910279, COSV53927635; called by muse, mutect2
- PCED1A | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 64/271 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62313608; called by muse, mutect2, varscan2
- PCLO | c.13218G>T p.R4406S | Missense Mutation (SNP) | VAF 188/557 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs767015823, COSV100438797; called by muse, mutect2, varscan2
- PDGFRB | c.1880C>T p.A627V | Missense Mutation (SNP) | VAF 120/432 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.46); catalogued as rs1201625387, COSV55810795; called by muse, varscan2
- PDGFRB | c.1685A>G p.Y562C | Missense Mutation (SNP) | VAF 53/308 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55811673; called by muse, mutect2, varscan2
- PDLIM2 | c.806C>T p.S269F (on ENST00000397760; = p.S519F on NM_021630.6) | Missense Mutation (SNP) | VAF 48/456 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs1276754364; called by muse, mutect2, varscan2
- PHC2 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 175/598 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as COSV57106119; called by muse, mutect2, varscan2
- PHEX | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1001397873; called by muse, mutect2
- PHPT1 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 124/435 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs774675816; called by muse, varscan2
- PIGC | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 85/175 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.795); catalogued as rs1362429049; called by muse, mutect2, varscan2
- PIK3AP1 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59530622; called by muse, mutect2
- PKD1L1 | c.4264C>T p.L1422F | Missense Mutation (SNP) | VAF 79/503 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56959173; called by muse, mutect2, varscan2
- PLEKHG5 | c.2869C>T p.P957S (on ENST00000400915 / NM_001042663.3; = p.P920S on NM_020631.6) | Missense Mutation (SNP) | VAF 209/649 reads (32%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1206960475; called by muse, mutect2, varscan2
- PLOD1 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 165/332 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as rs886039207; called by muse, varscan2
- PMEL | c.179G>A p.C60Y | Missense Mutation (SNP) | VAF 67/251 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs932634726, COSV62429232; called by muse, mutect2, varscan2
- PMP22 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 26/574 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CM983883; called by muse, mutect2
- PMS1 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 87/280 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59716011; called by muse, mutect2, varscan2
- PNPLA6 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 32/980 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.079); catalogued as rs947342898; called by muse, mutect2
- POC1B | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1435597219, COSV57964787; called by muse, mutect2, varscan2
- POLE3 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 72/286 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.175); catalogued as rs761753896; called by muse, mutect2, varscan2
- POLN | c.2060G>T p.G687V | Missense Mutation (SNP) | VAF 28/447 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67028072; called by muse, mutect2
- POM121L2 | c.2849G>A p.R950H | Missense Mutation (SNP) | VAF 120/391 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs750547129, COSV66276380; called by muse, mutect2, varscan2
- POU2F1 | c.332G>A p.G111E (on ENST00000541643 / NM_001365848.1; = p.G134E on NM_002697.4) | Missense Mutation (SNP) | VAF 15/262 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99610465; called by muse, mutect2
- PPAN-P2RY11 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 145/807 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as rs951325132; called by muse, mutect2, varscan2
- PPP1R16B | c.1603G>A p.V535I | Missense Mutation (SNP) | VAF 84/362 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV100240231; called by muse, mutect2, varscan2
- PPP2R5D | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs1349567425; called by muse, mutect2, varscan2
- PRDM8 | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 28/517 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV60203227; called by muse, mutect2
- PRKCG | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 66/504 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs145197557; called by muse, mutect2, varscan2
- PRPF3 | c.1758G>A p.G586= | Splice Region (SNP) | VAF 42/83 reads (51%) | catalogued as COSV61395315; called by muse, mutect2, varscan2
- PRPF40B | c.997A>G p.K333E (on ENST00000380281; = p.K327E on NM_012272.3) | Missense Mutation (SNP) | VAF 197/417 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1317868299; called by muse, mutect2, varscan2
- PRRC2C | c.1229C>T p.P410L (on ENST00000367742; = p.P408L on NM_015172.4) | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1454218240; called by muse, mutect2
- PSAPL1 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 42/607 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.096); catalogued as COSV59843684; called by muse, mutect2
- PSIP1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 56/100 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV66255795; called by muse, mutect2, varscan2
- PSKH2 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 24/437 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV52610642; called by muse, mutect2
- PSMD1 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 89/302 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV58076835; called by muse, mutect2, varscan2
- PTGES | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 177/359 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs753334822, COSV61393658; called by muse, mutect2, varscan2
- PVALB | c.46G>A p.V16M | Missense Mutation (SNP) | VAF 22/679 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs1314324113; called by muse, mutect2
- RAB12 | c.285C>T p.I95= | Splice Region (SNP) | VAF 14/273 reads (5%) | catalogued as COSV100251410; called by muse, mutect2
- RAB3GAP1 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 13/251 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51482901; called by muse, mutect2
- RASGRP3 | c.1202C>T p.P401L (on ENST00000402538 / NM_001349975.2; = p.P400L on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.019); catalogued as rs1405773090, COSV67822434; called by muse, varscan2
- RBM12B | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 122/481 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.101); catalogued as COSV101234477, COSV67897883; called by muse, mutect2, varscan2
- RECQL5 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 55/213 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs765553954; called by muse, mutect2, varscan2
- RERE | c.1906G>A p.V636M | Missense Mutation (SNP) | VAF 68/276 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.331); catalogued as rs773191046; called by muse, mutect2, varscan2
- RFC1 | c.1847G>C p.R616P | Missense Mutation (SNP) | VAF 104/313 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as COSV62899387; called by muse, mutect2, varscan2
- RHBDD2 | c.554G>A p.S185N | Missense Mutation (SNP) | VAF 45/562 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs782324035; called by muse, mutect2
- RINL | c.1160C>T p.A387V (on ENST00000591812 / NM_001195833.2; = p.A273V on NM_198445.4) | Missense Mutation (SNP) | VAF 38/1376 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs929243720; called by muse, mutect2
- RNF167 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 84/228 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs766054240; called by muse, mutect2, varscan2
- RNF19B | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.469); catalogued as COSV52389544; called by muse, mutect2
- RNF40 | c.968G>A p.G323D | Missense Mutation (SNP) | VAF 81/340 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV61213297; called by muse, mutect2, varscan2
- ROBO3 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101185108; called by muse, mutect2, varscan2
- RP1L1 | c.4925C>T p.A1642V | Missense Mutation (SNP) | VAF 30/680 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs1361812646; called by muse, mutect2
- RRP1 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs748501232; called by muse, mutect2, varscan2
- RSPH3 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 53/287 reads (18%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs756954187; called by muse, mutect2, varscan2
- RTL3 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as rs1450495384, COSV58183355; called by muse, mutect2
- RUNX1 | c.653C>T p.P218L (on ENST00000344691 / NM_001001890.3; = p.P245L on NM_001754.5) | Missense Mutation (SNP) | VAF 173/639 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs1048311302, COSV55871699; called by muse, mutect2, varscan2
- SCN1A | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 80/317 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs1213769949; called by muse, mutect2, varscan2
- SCN7A | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 91/263 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV69270806; called by muse, mutect2, varscan2
- SCNN1G | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 208/426 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs368523916; called by muse, varscan2
- SEC14L3 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 121/390 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.718); catalogued as rs1320554493; called by muse, mutect2, varscan2
- SEC24C | c.2575G>A p.V859I | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs1447819724, COSV59544967; called by muse, varscan2
- SEMA7A | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 98/347 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as rs566520642; called by muse, mutect2, varscan2
- SEPTIN1 | c.704G>T p.R235L (on ENST00000321367; = p.R188L on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as COSV58442866; called by muse, varscan2
- SERINC4 | c.1516C>T p.H506Y | Missense Mutation (SNP) | VAF 86/325 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.255); catalogued as rs192035160; called by muse, mutect2, varscan2
- SERPINA9 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 18/417 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as rs1258111947; called by muse, mutect2
- SERPINB1 | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 103/326 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs779711163; called by muse, mutect2, varscan2
- SFXN1 | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1285550775; called by muse, mutect2, varscan2
- SGCZ | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 96/204 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs772544113, COSV101170775, COSV66033304; called by muse, mutect2, varscan2
- SGSM1 | c.3421G>A p.V1141M (on ENST00000400359 / NM_001039948.4; = p.V1080M on NM_133454.3) | Missense Mutation (SNP) | VAF 90/359 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV68511394; called by muse, mutect2, varscan2
- SHANK2 | c.5402G>A p.G1801D | Missense Mutation (SNP) | VAF 25/432 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782544299; called by muse, mutect2
- SIPA1 | c.2261T>C p.V754A | Missense Mutation (SNP) | VAF 30/772 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs1032180213; called by muse, mutect2
- SLC22A18 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 138/540 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1298195419; called by muse, varscan2
- SLC2A11 | c.677G>A p.C226Y (on ENST00000345044 / NM_001024938.4; = p.C233Y on NM_030807.5) | Missense Mutation (SNP) | VAF 125/354 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1317961061; called by muse, mutect2, varscan2
- SLC35E2B | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 142/726 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1241185135; called by muse, mutect2, varscan2
- SLC38A9 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs769081599, COSV100591358; called by muse, mutect2, varscan2
- SLC39A6 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 23/397 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52372028; called by muse, mutect2
- SLC39A9 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752228108; called by muse, mutect2, varscan2
- SLC46A2 | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 46/456 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65289494, COSV65289890; called by muse, mutect2, varscan2
- SLC6A16 | c.2102C>T p.T701I | Missense Mutation (SNP) | VAF 26/522 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as rs1250279685; called by muse, mutect2
- SLC9A4 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 24/480 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54834035; called by muse, mutect2
- SMOC1 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 93/302 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV100734758; called by muse, mutect2, varscan2
- SMU1 | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as rs1290277193; called by muse, mutect2, varscan2
- SNX18 | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 30/914 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.898); catalogued as rs1209228724; called by muse, mutect2
- SOWAHB | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 37/576 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV57555724; called by muse, mutect2
- SP3 | c.2123G>A p.G708D | Missense Mutation (SNP) | VAF 51/284 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as rs745932652; called by muse, mutect2, varscan2
- SPATS2L | c.1478C>T p.S493F | Missense Mutation (SNP) | VAF 107/426 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.204); catalogued as COSV62349591; called by muse, mutect2, varscan2
- SPEG | c.6899C>T p.P2300L | Missense Mutation (SNP) | VAF 33/744 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1443992230; called by muse, mutect2
- SRGAP1 | c.3223C>T p.P1075S | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs755941243; called by muse, mutect2, varscan2
- SRRM4 | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 384/782 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); catalogued as rs1009179739; called by muse, mutect2, varscan2
- SRSF4 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV65695684; called by muse, mutect2, varscan2
- SSH3 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 28/660 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs936127278; called by muse, mutect2
- STAB2 | c.4936-1G>A p.X1646_splice | Splice Site (SNP) | VAF 93/280 reads (33%) | catalogued as rs1172151264; called by muse, mutect2, varscan2
- STARD9 | c.10648G>A p.G3550S | Missense Mutation (SNP) | VAF 16/430 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.044); catalogued as rs1244005746; called by muse, mutect2
- STXBP3 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 53/288 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.715); catalogued as COSV64182933; called by muse, varscan2
- SUCLA2 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as rs1422790610; called by muse, varscan2
- SYCP2L | c.2075C>T p.S692F | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.525); catalogued as rs988886610, COSV99305856; called by muse, mutect2, varscan2
- SYMPK | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 90/382 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs1168586162; called by muse, mutect2, varscan2
- SYNGAP1 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 126/559 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV53385759; called by muse, mutect2, varscan2
- TACC2 | c.4532G>A p.G1511D | Missense Mutation (SNP) | VAF 14/277 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs907056248; called by muse, mutect2
- TAF3 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100719925; called by muse, mutect2, varscan2
- TAFA2 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 141/283 reads (50%) | catalogued as COSV101352965, COSV101353930, COSV69178548; called by muse, mutect2, varscan2
- TAP2 | c.1385C>T p.T462I | Missense Mutation (SNP) | VAF 33/765 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.135); catalogued as COSV66500837; called by muse, mutect2
- TAS1R2 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 22/525 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs1488409276, COSV64743412; called by muse, mutect2
- TAS2R30 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 83/350 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV101115669; called by muse, mutect2, varscan2
- TASOR | c.1523G>A p.G508D (on ENST00000355628 / NM_001365636.2; = p.G112D on NM_015224.3) | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.124); catalogued as rs141369589; called by muse, mutect2, varscan2
- TBC1D30 | c.2146C>T p.P716S (on ENST00000542120; = p.P553S on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/381 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs1321697379, COSV57481072; called by muse, mutect2, varscan2
- TBX19 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 266/268 reads (99%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as rs199644548, COSV100892370; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCEAL5 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as rs751116979; called by muse, mutect2, varscan2
- TERT | c.659G>A p.G220D | Missense Mutation (SNP) | VAF 221/664 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.54); catalogued as COSV57221841; called by muse, mutect2, varscan2
- TESPA1 | c.814C>T p.R272* (on ENST00000316577 / NM_001098815.3; = p.R134* on NM_014796.2 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 201/397 reads (51%) | catalogued as rs759038034; called by muse, mutect2, varscan2
- TGS1 | c.2540G>A p.R847Q | Missense Mutation (SNP) | VAF 47/256 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as rs557221856; called by muse, mutect2, varscan2
- THEG | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 124/768 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as rs1428112975; called by muse, mutect2, varscan2
- TICAM1 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 285/1166 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.059); catalogued as rs1397775692, COSV50229835; called by muse, mutect2, varscan2
- TIE1 | c.2171G>A p.G724E | Missense Mutation (SNP) | VAF 120/440 reads (27%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.98); catalogued as rs772425017, COSV65249011; called by muse, mutect2, varscan2
- TLR10 | c.2411C>T p.S804F | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.317); catalogued as COSV58301647; called by muse, mutect2, varscan2
- TMBIM4 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 103/391 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as rs1215575752; called by muse, mutect2, varscan2
- TMEM125 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 232/829 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as rs757423930; called by muse, mutect2, varscan2
- TMEM159 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 113/355 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1567201166; called by muse, mutect2
- TMEM215 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 82/422 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV61363293; called by muse, mutect2, varscan2
- TMEM218 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 146/471 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV99692544; called by muse, mutect2, varscan2
- TMEM67 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 71/341 reads (21%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as COSV100018506; called by muse, mutect2, varscan2
- TMEM69 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs777574511; called by muse, mutect2, varscan2
- TMEM94 | c.3482C>T p.P1161L | Missense Mutation (SNP) | VAF 74/297 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100050262; called by muse, mutect2, varscan2
- TNFRSF21 | c.1423C>T p.L475F | Missense Mutation (SNP) | VAF 28/661 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57282613; called by muse, mutect2
- TNKS1BP1 | c.2251G>A p.G751S | Missense Mutation (SNP) | VAF 28/490 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.058); catalogued as COSV100836017; called by muse, mutect2
- TNS2 | c.251C>T p.P84L (on ENST00000314250 / NM_170754.4; = p.P94L on NM_015319.2) | Missense Mutation (SNP) | VAF 80/300 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1483324276, COSV58578730; called by muse, mutect2, varscan2
- TNS2 | c.2044C>T p.P682S (on ENST00000314250 / NM_170754.4; = p.P692S on NM_015319.2) | Missense Mutation (SNP) | VAF 24/520 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs1170348698; called by muse, mutect2
- TOGARAM1 | c.4255G>A p.D1419N | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV63892690; called by muse, mutect2, varscan2
- TP53I13 | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 142/496 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs766538307; called by muse, mutect2, varscan2
- TP73 | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 91/416 reads (22%) | catalogued as rs1361031582; called by muse, mutect2, varscan2
- TPR | c.5060C>T p.A1687V | Missense Mutation (SNP) | VAF 21/422 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV66605027; called by muse, mutect2
- TRIM13 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53948361; called by muse, mutect2, varscan2
- TRMT2A | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 76/392 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs1219139721; called by muse, mutect2, varscan2
- TRPM8 | c.3165G>A p.W1055* | Nonsense Mutation (SNP) | VAF 42/181 reads (23%) | catalogued as COSV61222091; called by muse, mutect2, varscan2
- TSC22D1 | c.1613G>A p.S538N | Missense Mutation (SNP) | VAF 116/177 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs961076555; called by muse, mutect2, varscan2
- TSPYL1 | c.856C>T p.H286Y | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218044981; called by muse, mutect2
- TSR3 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 63/300 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1255314666; called by muse, mutect2, varscan2
- TTBK1 | c.3656G>A p.G1219E | Missense Mutation (SNP) | VAF 160/894 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as rs755972016; called by muse, mutect2, varscan2
- TTN | c.76912C>T p.P25638S (on ENST00000591111; = p.P18214S on NM_003319.4) | Missense Mutation (SNP) | VAF 22/470 reads (5%) | PolyPhen benign (0.121); catalogued as rs1323358528; called by muse, mutect2
- TXNL4B | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 17/247 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as rs1243057512; called by muse, mutect2
- UGT2B4 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 45/224 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV59315285; called by muse, mutect2, varscan2
- UMODL1 | c.3371C>T p.P1124L (on ENST00000408910 / NM_001004416.2; = p.P1252L on NM_173568.3) | Missense Mutation (SNP) | VAF 80/346 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68570383; called by muse, mutect2, varscan2
- UNC45B | c.1418C>T p.T473I | Missense Mutation (SNP) | VAF 116/342 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs112484488; called by muse, mutect2
- UPK1A | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 60/678 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.525); catalogued as rs774668025; called by muse, mutect2
- URI1 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 85/573 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.009); catalogued as rs754863175; called by muse, mutect2, varscan2
- USP11 | c.2773C>T p.L925F (on ENST00000218348; = p.L882F on NM_001371072.1) | Missense Mutation (SNP) | VAF 16/303 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54475197; called by muse, mutect2
- USP24 | c.4411G>A p.D1471N | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as COSV53774320; called by muse, mutect2
- USP33 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 57/241 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.542); catalogued as rs1279482160; called by muse, mutect2, varscan2
- USP7 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 71/223 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as rs753971593; called by muse, mutect2, varscan2
- VAV1 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 94/415 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV58384859; called by muse, mutect2, varscan2
- VPS16 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 92/366 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV66793878; called by muse, mutect2, varscan2
- VWA3B | c.1718C>T p.S573F | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.878); catalogued as rs754424259; called by muse, mutect2, varscan2
- WDR5B | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 104/363 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs780221712; called by muse, mutect2, varscan2
- WDR64 | c.2057G>A p.R686Q | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs555147652, COSV63793914; called by muse, mutect2, varscan2
- WDR77 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 87/481 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.198); catalogued as rs1484049925; called by muse, mutect2, varscan2
- WDR81 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 18/384 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs377268135; called by muse, mutect2
- WDR87 | c.5383G>A p.E1795K | Missense Mutation (SNP) | VAF 28/796 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.051); catalogued as rs1226853523; called by muse, mutect2
- WIZ | c.4861G>A p.A1621T (on ENST00000673675 / NM_001371589.1; = p.A526T on NM_021241.3) | Missense Mutation (SNP) | VAF 57/486 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.194); catalogued as COSV54606816; called by muse, mutect2, varscan2
- WRNIP1 | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 69/240 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as rs749398278; called by muse, mutect2, varscan2
- YAE1 | c.158G>A p.G53D | Missense Mutation (SNP) | VAF 28/285 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56232512; called by muse, varscan2
- YEATS2 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 15/233 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59368208; called by muse, mutect2
- YJU2 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 80/487 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99508394; called by muse, varscan2
- YY1AP1 | c.1657C>T p.P553S (on ENST00000295566 / NM_139118.2; = p.P496S on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/700 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.954); catalogued as COSV99803979; called by muse, mutect2, varscan2
- ZBTB33 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 91/213 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV58535290; called by muse, mutect2, varscan2
- ZCCHC8 | c.2000C>T p.A667V | Missense Mutation (SNP) | VAF 39/361 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as rs1002996700, COSV60319335; called by muse, mutect2, varscan2
- ZDHHC5 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 225/458 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as rs1217640850; called by muse, mutect2, varscan2
- ZHX1 | c.863C>T p.T288I | Missense Mutation (SNP) | VAF 49/380 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs776929418; called by muse, mutect2, varscan2
- ZNF100 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 83/420 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.463); catalogued as rs369863367; called by muse, mutect2, varscan2
- ZNF106 | c.2090C>T p.A697V | Missense Mutation (SNP) | VAF 72/332 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1420241441; called by muse, mutect2, varscan2
- ZNF174 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 22/501 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1459949213; called by muse, mutect2
- ZNF30 | c.1774G>A p.G592S | Missense Mutation (SNP) | VAF 48/669 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs767253813; called by muse, mutect2
- ZNF318 | c.5641C>T p.Q1881* | Nonsense Mutation (SNP) | VAF 93/234 reads (40%) | catalogued as rs1225238383, COSV58932454; called by muse, mutect2, varscan2
- ZNF362 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 24/710 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1355772379; called by muse, mutect2
- ZNF462 | c.2510G>A p.G837D | Missense Mutation (SNP) | VAF 17/422 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1340387330; called by muse, mutect2
- ZNF469 | c.6025G>A p.E2009K (on ENST00000437464; = p.E2037K on NM_001367624.2) | Missense Mutation (SNP) | VAF 46/677 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0.219); catalogued as COSV71259386; called by muse, mutect2
- ZNF492 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 42/343 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs199628235; called by muse, mutect2
- ZNF609 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 66/311 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100441800; called by muse, mutect2, varscan2
- ZNF609 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 40/371 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs747087167; called by muse, mutect2, varscan2
- ZNF638 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 58/266 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs1021893917; called by muse, mutect2, varscan2
- ZNF641 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1474867339; called by muse, mutect2, varscan2
- ZNF703 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 54/870 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs911068285; called by muse, mutect2
- ZNF768 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 61/482 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV53224713; called by muse, mutect2, varscan2
- ZNF80 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV57360128; called by muse, mutect2
- ZNF841 | c.919C>T p.H307Y (on ENST00000426391 / NM_001369830.1; = p.H423Y on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/436 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100744909; called by muse, mutect2
- ZNRF3 | c.1144C>T p.P382S (on ENST00000544604 / NM_001206998.2; = p.P282S on NM_032173.3) | Missense Mutation (SNP) | VAF 169/596 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV60431904; called by muse, mutect2, varscan2
- ZP2 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 14/404 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV54816473; called by muse, mutect2
- ZSWIM2 | c.1807C>T p.R603* | Nonsense Mutation (SNP) | VAF 79/235 reads (34%) | catalogued as rs750650865; called by muse, mutect2, varscan2
- ABCA12 | c.1330G>A p.E444K (on ENST00000272895 / NM_173076.3; = p.E126K on NM_015657.3) | Missense Mutation (SNP) | VAF 78/280 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- ABCA13 | c.5603G>A p.G1868D | Missense Mutation (SNP) | VAF 83/471 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ABCA13 | c.11336-1G>A p.X3779_splice | Splice Site (SNP) | VAF 50/232 reads (22%) | called by muse, mutect2, varscan2
- ABCA6 | c.3110G>A p.S1037N | Missense Mutation (SNP) | VAF 19/326 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.087); called by muse, mutect2
- ABCA6 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- ABCB8 | c.1175G>A p.G392D (on ENST00000297504 / NM_001282291.2; = p.G375D on NM_007188.5) | Missense Mutation (SNP) | VAF 22/453 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2
- ABCC6 | c.2415+1G>A p.X805_splice | Splice Site (SNP) | VAF 72/276 reads (26%) | called by muse, varscan2
- ABHD8 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 40/1354 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- ABTB2 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 22/578 reads (4%) | SIFT tolerated (0.82); PolyPhen benign (0.001); called by muse, mutect2
- AC008878.3 | c.63G>A p.K21= | Splice Region (SNP) | VAF 62/356 reads (17%) | called by muse, mutect2, varscan2
- AC098582.1 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 73/269 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACACA | c.4880C>T p.A1627V | Missense Mutation (SNP) | VAF 17/438 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACACB | c.2966G>A p.G989E | Missense Mutation (SNP) | VAF 90/456 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACAN | c.1396A>G p.T466A | Missense Mutation (SNP) | VAF 127/445 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACAP2 | c.2090G>A p.G697D | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACOX1 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- ACOX2 | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 21/424 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- ACP2 | c.549+1G>A p.X183_splice | Splice Site (SNP) | VAF 30/271 reads (11%) | called by muse, varscan2
- ADAD1 | c.392G>A p.C131Y | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAM10 | c.130del p.Q44Kfs*19 | Frame Shift Del (DEL) | VAF 133/365 reads (36%) | called by mutect2, pindel, varscan2
- ADAM22 | c.2590G>A p.A864T (on ENST00000265727 / NM_001324420.2; = p.A828T on NM_016351.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/305 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAM32 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ADAM32 | c.1774G>A p.D592N | Missense Mutation (SNP) | VAF 53/319 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- ADAM33 | c.600G>A p.R200= | Splice Region (SNP) | VAF 76/270 reads (28%) | called by muse, mutect2, varscan2
- ADAMTS1 | c.2751G>A p.W917* | Nonsense Mutation (SNP) | VAF 26/358 reads (7%) | called by muse, mutect2
- ADAMTS7 | c.5026C>T p.P1676S | Missense Mutation (SNP) | VAF 28/666 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); called by muse, mutect2
- ADAR | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 70/984 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADCY5 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 123/609 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ADGRA3 | c.3634G>A p.G1212S | Missense Mutation (SNP) | VAF 24/507 reads (5%) | SIFT tolerated (0.89); PolyPhen benign (0.001); called by muse, mutect2
- ADGRD2 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 27/1056 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0.024); called by muse, mutect2
- ADGRE1 | c.1495C>T p.Q499* | Nonsense Mutation (SNP) | VAF 41/601 reads (7%) | called by muse, mutect2
- ADHFE1 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 79/293 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADM | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 64/625 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2
- ADRA2A | c.994G>A p.G332S | Missense Mutation (SNP) | VAF 179/357 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AFF3 | c.3001G>A p.A1001T | Missense Mutation (SNP) | VAF 113/286 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AGO4 | c.372G>A p.W124* | Nonsense Mutation (SNP) | VAF 97/373 reads (26%) | called by muse, mutect2, varscan2
- AGTR2 | c.1031G>A p.R344K | Missense Mutation (SNP) | VAF 117/193 reads (61%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- AHI1 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 52/91 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- AJM1 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 144/536 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AL031777.2 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); called by muse, mutect2
- ALDH1B1 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 54/456 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ALK | c.4165G>A p.D1389N | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); called by muse, mutect2
- ALMS1 | c.10256G>A p.G3419E | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2
- ALS2 | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- AMER3 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 61/557 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- AMH | c.1360G>A p.G454R | Missense Mutation (SNP) | VAF 40/1028 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.031); called by muse, mutect2
- AMT | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 155/513 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ANGPTL2 | c.962G>A p.R321K | Missense Mutation (SNP) | VAF 49/331 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- ANK3 | c.5398C>T p.L1800F | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANK3 | c.2393C>T p.T798I | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKRD11 | c.4147G>A p.G1383S | Missense Mutation (SNP) | VAF 144/495 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD18A | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ANKRD18A | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD27 | c.1361T>C p.V454A | Missense Mutation (SNP) | VAF 131/396 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- ANKRD28 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 17/249 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- ANKRD34B | c.1044G>C p.Q348H | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.049); called by muse, mutect2
- ANKRD36C | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- ANKRD61 | c.793C>T p.L265F | Missense Mutation (SNP) | VAF 128/676 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANLN | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 97/515 reads (19%) | called by muse, mutect2, varscan2
- ANO4 | c.2054G>A p.G685E (on ENST00000392977 / NM_001286615.2; = p.G650E on NM_178826.4) | Missense Mutation (SNP) | VAF 22/365 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.062); called by muse, mutect2
- ANO8 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 183/1042 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, varscan2
- AP5M1 | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- APBB3 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 17/375 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); called by muse, mutect2
- ARAP3 | c.4510G>A p.G1504R | Missense Mutation (SNP) | VAF 111/430 reads (26%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF11 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 91/595 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF12 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 40/275 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ARHGEF2 | c.1637C>T p.P546L (on ENST00000361247 / NM_001162383.2; = p.P518L on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/1156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGEF3 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- ARID1A | c.2294C>T p.P765L | Missense Mutation (SNP) | VAF 22/455 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARID2 | c.4439G>A p.G1480E | Missense Mutation (SNP) | VAF 19/384 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARID3A | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 125/695 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- ARIH1 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 47/236 reads (20%) | called by muse, mutect2, varscan2
- ARMC5 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 141/516 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ARMC7 | c.464G>A p.R155K | Missense Mutation (SNP) | VAF 25/682 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.493); called by muse, mutect2
- ARMC8 | c.1725G>A p.Q575= (on ENST00000469044 / NM_001363941.2; = p.Q561= on NM_015396.6) | Splice Region (SNP) | VAF 31/168 reads (18%) | called by muse, mutect2, varscan2
- AS3MT | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ASAP1 | c.2525C>T p.P842L | Missense Mutation (SNP) | VAF 21/470 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- ASCC3 | c.2951C>T p.T984I | Missense Mutation (SNP) | VAF 82/262 reads (31%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- ASMT | c.980G>A p.R327K (on ENST00000381229; = p.R355K on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 168/620 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASXL2 | c.4048G>A p.V1350I | Missense Mutation (SNP) | VAF 52/279 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- ATAD5 | c.4070C>T p.P1357L | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ATG2A | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 125/468 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATN1 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 41/478 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.705); called by muse, mutect2
- ATP11C | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- ATP1A2 | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 32/1091 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATP2C2 | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- ATP4A | c.2695G>A p.A899T | Missense Mutation (SNP) | VAF 135/734 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ATXN2 | c.2660C>T p.T887I (on ENST00000550104; = p.T727I on NM_002973.4) | Missense Mutation (SNP) | VAF 83/246 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATXN2L | c.2446C>T p.P816S | Missense Mutation (SNP) | VAF 82/326 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- AWAT1 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.185); called by muse, mutect2
- B4GALNT1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 98/424 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- BCAM | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 114/416 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.321); called by muse, varscan2
- BCO1 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 96/343 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- BCORL1 | c.2561C>T p.P854L | Missense Mutation (SNP) | VAF 232/375 reads (62%) | SIFT tolerated (0.2); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- BEGAIN | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 34/980 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- BICDL1 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 138/296 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, varscan2
- BIRC2 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 86/306 reads (28%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- BIRC7 | c.659G>A p.S220N | Missense Mutation (SNP) | VAF 22/558 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.025); called by muse, mutect2
- BMS1 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 94/164 reads (57%) | SIFT tolerated (0.35); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- BNIP5 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 132/482 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BOC | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 28/522 reads (5%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.968); called by muse, mutect2
- BPIFB2 | c.1149G>A p.G383= | Splice Region (SNP) | VAF 71/443 reads (16%) | called by muse, mutect2, varscan2
- BPTF | c.8269G>A p.A2757T | Missense Mutation (SNP) | VAF 58/233 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BRD8 | c.1498G>A p.D500N (on ENST00000254900 / NM_139199.2; = p.D573N on NM_006696.4) | Missense Mutation (SNP) | VAF 52/369 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- BRSK1 | c.1250C>T p.T417I | Missense Mutation (SNP) | VAF 131/602 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- BRSK2 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 20/486 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.006); called by muse, mutect2
- BSDC1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 62/323 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTBD18 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 45/390 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BTN2A1 | c.1164G>A p.W388* | Nonsense Mutation (SNP) | VAF 77/336 reads (23%) | called by muse, mutect2, varscan2
- C11orf87 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 32/700 reads (5%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.236); called by muse, mutect2
- C1orf216 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 105/362 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- C2orf72 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 83/402 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C7orf26 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 57/549 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- CA4 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 31/731 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.452); called by muse, mutect2
- CA7 | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 62/380 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- CACNA1F | c.3314C>T p.P1105L | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CAMK2D | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CAPN15 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 99/529 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPN5 | c.2027C>T p.S676F (on ENST00000456580; = p.S636F on NM_004055.5) | Missense Mutation (SNP) | VAF 104/353 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- CARD14 | c.2925G>A p.W975* | Nonsense Mutation (SNP) | VAF 223/750 reads (30%) | called by muse, mutect2, varscan2
- CARHSP1 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 16/376 reads (4%) | SIFT tolerated (0.92); PolyPhen benign (0.005); called by muse, mutect2
- CAST | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 159/564 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CATSPERE | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 36/455 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2
- CBR1 | c.368_369insGTC p.T123_E124insS | In Frame Ins (INS) | VAF 160/369 reads (43%) | called by mutect2, pindel, varscan2
- CC2D1A | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2
- CCDC120 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 24/361 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- CCDC138 | c.1352G>C p.R451T | Missense Mutation (SNP) | VAF 85/197 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- CCDC146 | c.1742G>A p.R581K | Missense Mutation (SNP) | VAF 72/338 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CCDC157 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 150/483 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CCDC168 | c.19052C>T p.S6351F | Missense Mutation (SNP) | VAF 80/162 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC180 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC51 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 21/460 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CCDC59 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 100/407 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC63 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 113/419 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- CCDC86 | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 32/621 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2
- CCND1 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 128/499 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.148); called by muse, varscan2
- CCNT1 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCR10 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 21/510 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- CD163 | c.359G>A p.C120Y | Missense Mutation (SNP) | VAF 26/462 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CD163 | c.125G>A p.S42N | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD180 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 26/309 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2
- CDA | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 59/369 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC27 | c.383C>T p.T128I | Missense Mutation (SNP) | VAF 96/194 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- CDH15 | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 212/690 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDH4 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 100/713 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDIN1 | c.568G>A p.G190S (on ENST00000437989; = p.G92S on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/239 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK15 | c.1205C>T p.S402F (on ENST00000652192 / NM_001366386.2; = p.S351F on NM_139158.2) | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- CDK5RAP3 | c.920G>A p.G307D | Missense Mutation (SNP) | VAF 74/318 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CDRT15L2 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 44/260 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CELA2B | c.763G>C p.V255L | Missense Mutation (SNP) | VAF 77/367 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CELSR2 | c.4595C>T p.P1532L | Missense Mutation (SNP) | VAF 100/1568 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CEP192 | c.5175-1G>A p.X1725_splice | Splice Site (SNP) | VAF 29/181 reads (16%) | called by muse, mutect2, varscan2
- CEP250 | c.1093C>T p.H365Y | Missense Mutation (SNP) | VAF 25/266 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- CES2 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 113/424 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP20DC | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 15/306 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CHD3 | c.4741G>A p.E1581K | Missense Mutation (SNP) | VAF 104/177 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CHD4 | c.3805G>A p.V1269M (on ENST00000357008 / NM_001363606.2; = p.V1282M on NM_001273.5) | Missense Mutation (SNP) | VAF 16/400 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CHD8 | c.1154G>A p.G385E (on ENST00000646647 / NM_001170629.2; = p.G106E on NM_020920.4) | Missense Mutation (SNP) | VAF 101/172 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CHMP1A | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 17/331 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- CHRM3 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 92/344 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIAO1 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 145/563 reads (26%) | SIFT tolerated (0.97); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CIC | c.2176G>A p.G726R | Missense Mutation (SNP) | VAF 24/704 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- CKB | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 186/822 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CLASRP | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.023); called by muse, mutect2
- CLCA2 | c.2117G>A p.G706E | Missense Mutation (SNP) | VAF 84/256 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- CLHC1 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- CLIP3 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 173/904 reads (19%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CLPTM1 | c.1623G>A p.W541* | Nonsense Mutation (SNP) | VAF 29/675 reads (4%) | called by muse, mutect2
- CLPTM1 | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 28/758 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- CLPTM1L | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 120/401 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- CLSTN3 | c.2143G>A p.D715N | Missense Mutation (SNP) | VAF 60/406 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, varscan2
- CLTC | c.2267C>T p.P756L | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- CMYA5 | c.3793G>A p.E1265K | Missense Mutation (SNP) | VAF 38/446 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); called by muse, mutect2
- CNKSR2 | c.2116C>T p.P706S | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- CNTD1 | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 48/342 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTROB | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 15/276 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2
- COG5 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 90/289 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL11A2 | c.3560C>T p.P1187L (on ENST00000341947 / NM_080680.3; = p.P1080L on NM_080679.2) | Missense Mutation (SNP) | VAF 132/451 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL12A1 | c.6343G>A p.G2115R | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- COL18A1 | c.2986G>A p.E996K (on ENST00000359759 / NM_130444.3; = p.E761K on NM_030582.4) | Missense Mutation (SNP) | VAF 88/416 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, varscan2
- COL19A1 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- COL1A1 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 60/376 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL27A1 | c.4621G>A p.G1541S | Missense Mutation (SNP) | VAF 91/314 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL2A1 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 98/336 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COL4A1 | c.4076C>A p.P1359H | Missense Mutation (SNP) | VAF 100/313 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, varscan2
- COL4A4 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 67/306 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL5A2 | c.1745G>A p.G582D | Missense Mutation (SNP) | VAF 63/249 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A2 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 18/412 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL6A3 | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 18/430 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2
- COL6A5 | c.5527G>A p.V1843I (on ENST00000312481; = p.V1839I on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/364 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- COL7A1 | c.2869G>A p.V957I | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- COMMD4 | c.4-1G>A p.X2_splice | Splice Site (SNP) | VAF 40/412 reads (10%) | called by muse, mutect2
- COPB2 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 86/303 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- COPS3 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 65/251 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- CPEB2 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 120/435 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.682); called by muse, varscan2
- CPNE7 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 23/402 reads (6%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2
- CPPED1 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 161/498 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CPSF1 | c.1608G>A p.W536* | Nonsense Mutation (SNP) | VAF 31/516 reads (6%) | called by muse, mutect2
- CRACD | c.2929C>G p.L977V | Missense Mutation (SNP) | VAF 17/439 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2
- CRACDL | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 35/966 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.022); called by muse, mutect2
- CRACDL | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 206/694 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- CRCP | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 136/760 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CRY1 | c.1475C>T p.S492L | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2
- CRYBG1 | c.5155C>T p.P1719S | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); called by muse, mutect2
- CRYBG3 | c.6505G>A p.E2169K | Missense Mutation (SNP) | VAF 37/327 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- CSPG4 | c.2038C>T p.P680S | Missense Mutation (SNP) | VAF 29/687 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.021); called by muse, mutect2
- CTDP1 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CTNND2 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CTRC | c.686G>A p.W229* | Nonsense Mutation (SNP) | VAF 21/596 reads (4%) | called by muse, mutect2
- CUBN | c.4388C>T p.A1463V | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); called by muse, mutect2
- CUBN | c.1034G>A p.R345K | Missense Mutation (SNP) | VAF 74/111 reads (67%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CUL5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 153/488 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUL9 | c.3088G>A p.V1030I | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CWC25 | c.1241C>T p.T414I | Missense Mutation (SNP) | VAF 15/400 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CYBB | c.230C>A p.S77Y | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP24A1 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 102/355 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CYP2D7 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 106/463 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CYP2S1 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 150/518 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CYP2S1 | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 109/525 reads (21%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.927); called by muse, varscan2
- CYSLTR2 | c.343T>C p.S115P | Missense Mutation (SNP) | VAF 97/147 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DBNDD1 | c.242C>T p.T81I (on ENST00000002501 / NM_001042610.3; = p.T101I on NM_024043.3) | Missense Mutation (SNP) | VAF 30/618 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- DCAF7 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 20/279 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- DCSTAMP | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 69/275 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- DDX11 | c.2581C>T p.P861S (on ENST00000545668 / NM_152438.2; = p.D812= on NM_004399.3) | Missense Mutation (SNP) | VAF 142/528 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- DDX55 | c.167G>A p.G56D | Missense Mutation (SNP) | VAF 61/219 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND1A | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.168); called by muse, mutect2
- DEPDC5 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 102/369 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DGKI | c.2644G>A p.D882N | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.104); called by muse, mutect2
- DHX9 | c.3791G>A p.G1264E | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DLG2 | c.1878G>A p.G626= | Splice Region (SNP) | VAF 76/237 reads (32%) | called by muse, mutect2, varscan2
- DLG2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 99/341 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- DMAP1 | c.302C>T p.T101I | Missense Mutation (SNP) | VAF 117/435 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- DMXL1 | c.6254C>T p.S2085F | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2
- DNAAF1 | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 76/309 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DNAH10 | c.8350G>A p.V2784M (on ENST00000409039; = p.V2723M on NM_207437.3) | Missense Mutation (SNP) | VAF 103/410 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAH17 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2
- DNAI2 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 16/400 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAJB4 | c.623G>A p.W208* | Nonsense Mutation (SNP) | VAF 44/232 reads (19%) | called by muse, mutect2, varscan2
- DNAJB6 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 86/308 reads (28%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJB7 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 60/315 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DNAJC13 | c.4711C>T p.Q1571* | Nonsense Mutation (SNP) | VAF 18/182 reads (10%) | called by muse, mutect2, varscan2
- DNAJC13 | c.6278G>A p.G2093D | Missense Mutation (SNP) | VAF 72/268 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DNM1 | c.2579C>T p.P860L | Missense Mutation (SNP) | VAF 91/391 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- DNM2 | c.2536G>A p.V846M (on ENST00000355667 / NM_001005360.3; = p.V842M on NM_004945.3) | Missense Mutation (SNP) | VAF 65/577 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- DNMT3A | c.1709G>A p.G570E | Missense Mutation (SNP) | VAF 115/384 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); called by muse, varscan2
- DOCK3 | c.2837C>T p.S946F | Missense Mutation (SNP) | VAF 91/337 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DOCK4 | c.3652G>A p.E1218K | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DOCK9 | c.3640G>A p.G1214R (on ENST00000376460 / NM_001366676.2; = p.G1215R on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/207 reads (67%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DOCK9 | c.26G>A p.S9N | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2
1,583 further variants in this file (747 protein-altering or splice-affecting, 739 silent, 97 other) are not listed here.
